Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4369, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4369-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Cardia. Tumor configuration: Not specified. Tumor size: 7 x 8 x 2 cm. Histologic type: Adenocarcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Esophagus Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file c78742e2-9c47-4d85-b347-e624d6bceb8a (TCGA-BR-4369.D42D65AF-E1EA-4C9D-A547-4041E05B775B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).